Somatic mutation profile of tumor specimen MMRF_2270_1_BM_CD138pos (aliquot MMRF_2270_1_BM_CD138pos_T2_KHS5U_K14023) from MMRF case MMRF_2270, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 56.5 years (20,654 days).
Specimen MMRF_2270_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aecfe7f7-3bb9-4302-981d-48eb04656c7b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2270_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2270_1_PB_Whole_C1_KHS5U_K14022; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc53096f-11a9-4456-aa64-a019dea7966f

The open-access MAF lists 107 somatic variants for this specimen: 46 protein-altering or splice-affecting, 13 silent, 48 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, 3'UTR 22, Intron 14, Silent 13, 5'UTR 6, RNA 3, Nonsense Mutation 2, Frame Shift Del 2, 5'Flank 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANP32A | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 108/272 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as COSV51189832; called by muse, mutect2, varscan2
- BRAF | c.356C>T p.T119I | Missense Mutation (SNP) | VAF 89/208 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.125); catalogued as COSV56192935; called by muse, mutect2, varscan2
- CEP78 | c.809A>G p.N270S | Missense Mutation (SNP) | VAF 63/155 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.054); catalogued as rs372759241; called by muse, mutect2, varscan2
- GPBP1 | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 82/171 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV53314224; called by muse, mutect2, varscan2
- H4C5 | c.226C>T p.H76Y | Missense Mutation (SNP) | VAF 126/272 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.544); catalogued as rs942850537; called by muse, mutect2, varscan2
- IGHV2-70 | c.255G>C p.K85N | Missense Mutation (SNP) | VAF 70/106 reads (66%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs370734838; called by muse, varscan2
- IGHV2-70 | c.253A>C p.K85Q | Missense Mutation (SNP) | VAF 70/108 reads (65%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs755889609; called by muse, varscan2
- IGHV2-70 | c.157A>C p.M53L | Missense Mutation (SNP) | VAF 62/96 reads (65%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs369368857; called by muse, varscan2
- IGHV2-70 | c.124A>G p.T42A | Missense Mutation (SNP) | VAF 42/65 reads (65%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.453); catalogued as rs373474286; called by muse, varscan2
- IGLV3-1 | c.113G>A p.S38N | Missense Mutation (SNP) | VAF 88/91 reads (97%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs61736462; called by muse, mutect2, varscan2
- IGLV3-1 | c.292G>C p.A98P | Missense Mutation (SNP) | VAF 89/94 reads (95%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); catalogued as rs534241034; called by muse, mutect2, varscan2
- KMT2C | c.14078G>A p.R4693Q | Missense Mutation (SNP) | VAF 82/182 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777526116, COSV51286192; called by muse, mutect2, varscan2
- PLB1 | c.1534G>A p.G512S | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.086); catalogued as rs750364063, COSV100214838; called by muse, mutect2, varscan2
- RGS7 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 59/187 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58552942; called by muse, mutect2, varscan2
- ZNF521 | c.482G>T p.R161L | Missense Mutation (SNP) | VAF 79/167 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64133304; called by muse, mutect2, varscan2
- ZNF616 | c.2014C>T p.R672W | Missense Mutation (SNP) | VAF 37/64 reads (58%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as rs146075861; called by muse, mutect2, varscan2
- ARHGEF17 | c.4451del p.F1484Sfs*2 | Frame Shift Del (DEL) | VAF 38/112 reads (34%) | called by mutect2, pindel, varscan2
- ASTE1 | c.1057C>G p.L353V | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATM | c.968_969del p.I323Kfs*6 | Frame Shift Del (DEL) | VAF 10/37 reads (27%) | called by mutect2, pindel, varscan2
- ATM | c.8300T>C p.L2767P | Missense Mutation (SNP) | VAF 76/160 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BRDT | c.2726A>C p.D909A | Missense Mutation (SNP) | VAF 36/36 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- CACNA2D1 | c.2058T>G p.F686L (on ENST00000356253 / NM_001366867.1; = p.F674L on NM_000722.4) | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CCDC146 | c.2029G>A p.E677K | Missense Mutation (SNP) | VAF 86/185 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- CFAP58 | c.1136T>C p.M379T | Missense Mutation (SNP) | VAF 130/328 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CSMD3 | c.6166C>G p.Q2056E (on ENST00000297405 / NM_001363185.1; = p.Q1952E on NM_052900.3) | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- CSTF2T | c.559G>T p.A187S | Missense Mutation (SNP) | VAF 65/139 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GBE1 | c.1766G>A p.R589K | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HSD11B1 | c.731A>G p.E244G | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- JAK3 | c.622G>A p.V208M | Missense Mutation (SNP) | VAF 63/150 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- KCNG3 | c.1244G>A p.C415Y | Missense Mutation (SNP) | VAF 88/193 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MYBPH | c.1007A>T p.Y336F | Missense Mutation (SNP) | VAF 90/334 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NCCRP1 | c.284T>C p.L95P | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLCE1 | c.6045A>T p.R2015S | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- POLR3E | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 61/134 reads (46%) | SIFT tolerated (0.46); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- RALGDS | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.52); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SERPINB13 | c.803T>G p.V268G | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- SIK3 | c.631C>T p.Q211* (on ENST00000445177 / NM_001366686.2; = p.Q217* on NM_025164.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 30/70 reads (43%) | called by muse, mutect2, varscan2
- SLC22A12 | c.1426G>T p.A476S | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- SMO | c.1473G>T p.Q491H | Missense Mutation (SNP) | VAF 26/209 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- SORCS1 | c.1452G>T p.K484N | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- SVEP1 | c.10093G>T p.E3365* | Nonsense Mutation (SNP) | VAF 57/128 reads (45%) | called by muse, mutect2, varscan2
- TGOLN2 | c.1255T>G p.S419A | Missense Mutation (SNP) | VAF 76/166 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- TMEM151A | c.1193G>A p.R398H | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TMEM214 | c.683A>C p.Q228P | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- TRIM77 | c.499A>T p.T167S | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VPS13D | c.2965A>C p.K989Q | Missense Mutation (SNP) | VAF 99/102 reads (97%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- ASPM | c.5755T>C p.L1919= | Silent (SNP) | VAF 87/285 reads (31%) | called by muse, mutect2, varscan2
- CCAR2 | c.1212C>A p.R404= | Silent (SNP) | VAF 83/176 reads (47%) | called by muse, mutect2, varscan2
- CD19 | c.1143G>A p.P381= | Silent (SNP) | VAF 35/69 reads (51%) | catalogued as rs757976340; called by muse, mutect2, varscan2
- DEF8 | c.429C>T p.V143= (on ENST00000268676 / NM_207514.3; = p.V82= on NM_017702.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/59 reads (44%) | catalogued as rs141475941, COSV51917861; called by muse, mutect2, varscan2
- DNAH1 | c.6519C>T p.Y2173= | Silent (SNP) | VAF 22/43 reads (51%) | catalogued as rs777504039, COSV70227733; called by muse, mutect2, varscan2
- GFRAL | c.396G>A p.L132= | Silent (SNP) | VAF 72/146 reads (49%) | catalogued as COSV100474656, COSV61231084; called by muse, mutect2, varscan2
- GLT8D2 | c.675T>C p.S225= | Silent (SNP) | VAF 4/35 reads (11%) | called by muse, mutect2, varscan2
- HUWE1 | c.10065G>A p.R3355= | Silent (SNP) | VAF 34/34 reads (100%) | called by muse, mutect2, varscan2
- MAP3K4 | c.1095A>G p.E365= | Silent (SNP) | VAF 105/211 reads (50%) | called by muse, mutect2, varscan2
- PODN | c.1129C>T p.L377= (on ENST00000395871; = p.L329= on NM_153703.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 107/107 reads (100%) | called by muse, mutect2, varscan2
- TGM6 | c.1191C>T p.A397= | Silent (SNP) | VAF 88/177 reads (50%) | catalogued as rs147554438; ClinVar: likely benign; called by muse, mutect2, varscan2
- TRAF4 | c.30G>A p.E10= | Silent (SNP) | VAF 75/147 reads (51%) | called by muse, mutect2, varscan2
- TRPV1 | c.1374G>A p.V458= | Silent (SNP) | VAF 46/99 reads (46%) | catalogued as COSV51514721; called by muse, mutect2, varscan2
- AHCTF1P1 | n.49G>A | RNA (SNP) | VAF 22/69 reads (32%) | catalogued as rs1167805965; called by muse, mutect2, varscan2
- ATG12 | c.*988G>C | 3'UTR (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2, varscan2
- ATP13A3 | c.*51G>T | 3'UTR (SNP) | VAF 38/63 reads (60%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021372 G>C | 5'Flank (SNP) | VAF 71/150 reads (47%) | catalogued as COSV55847988; called by muse, mutect2, varscan2
- BLK | c.1030-346T>G | Intron (SNP) | VAF 47/116 reads (41%) | called by muse, mutect2, varscan2
- CACFD1 | c.*1890C>T | 3'UTR (SNP) | VAF 80/153 reads (52%) | catalogued as rs900357096; called by muse, mutect2, varscan2
- CCDC136 | c.*84C>T | 3'UTR (SNP) | VAF 46/93 reads (49%) | catalogued as rs1440111404; called by muse, mutect2, varscan2
- CHRM3 | c.*4536C>G | 3'UTR (SNP) | VAF 93/136 reads (68%) | called by muse, mutect2, varscan2
- COASY | c.-362C>T | 5'UTR (SNP) | VAF 30/63 reads (48%) | called by muse, mutect2, varscan2
- COL18A1 | c.3597+180G>A | Intron (SNP) | VAF 85/224 reads (38%) | catalogued as rs951379587; called by muse, mutect2, varscan2
- CSNK1E | c.1218+44_1218+69del | Intron (DEL) | VAF 8/15 reads (53%) | called by mutect2, varscan2
- CYBRD1 | c.*621C>T | 3'UTR (SNP) | VAF 38/85 reads (45%) | catalogued as rs1345035341; called by muse, mutect2
- DACT2 | c.-23G>A | 5'UTR (SNP) | VAF 34/87 reads (39%) | called by muse, mutect2, varscan2
- DDHD1 | chr14:53153200 A>T | 5'Flank (SNP) | VAF 51/107 reads (48%) | catalogued as rs866672629; called by muse, mutect2, varscan2
- EWSR1 | c.*336del | 3'UTR (DEL) | VAF 3/28 reads (11%) | called by mutect2*, pindel, varscan2*
- FEM1AP2 | n.1123G>A | RNA (SNP) | VAF 7/22 reads (32%) | called by muse, mutect2, varscan2
- FREM2 | c.*569G>T | 3'UTR (SNP) | VAF 27/28 reads (96%) | called by muse, mutect2, varscan2
- GPR17 | c.*784G>A | 3'UTR (SNP) | VAF 47/98 reads (48%) | catalogued as rs374108061; called by muse, mutect2, varscan2
- GPR37 | c.*209A>G | 3'UTR (SNP) | VAF 56/115 reads (49%) | catalogued as rs1185086885; called by muse, mutect2, varscan2
- GTF3C2 | c.856-72A>T | Intron (SNP) | VAF 38/73 reads (52%) | called by muse, mutect2, varscan2
- HGSNAT | c.1465-211A>C | Intron (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2
- LHX1 | c.*351G>T | 3'UTR (SNP) | VAF 27/73 reads (37%) | called by muse, mutect2, varscan2
- LMLN | c.*4216T>G | 3'UTR (SNP) | VAF 35/67 reads (52%) | called by muse, mutect2, varscan2
- MACF1 | c.16491+479C>T | Intron (SNP) | VAF 7/102 reads (7%) | catalogued as COSV57110352; called by muse, mutect2
- MLXIP | c.738+58C>A | Intron (SNP) | VAF 94/147 reads (64%) | called by muse, mutect2, varscan2
- NT5E | c.1360+413G>T | Intron (SNP) | VAF 43/76 reads (57%) | called by muse, mutect2, varscan2
- NTRK2 | c.-301C>T | 5'UTR (SNP) | VAF 45/120 reads (38%) | called by muse, mutect2, varscan2
- ORAI3 | c.*1091C>T | 3'UTR (SNP) | VAF 13/27 reads (48%) | called by muse, mutect2, varscan2
- PPARGC1B | c.*5578G>T | 3'UTR (SNP) | VAF 31/66 reads (47%) | called by muse, mutect2, varscan2
- PTH2R | c.-155C>T | 5'UTR (SNP) | VAF 31/71 reads (44%) | called by muse, mutect2, varscan2
- RPL14P1 | n.156C>T | RNA (SNP) | VAF 67/146 reads (46%) | called by muse, mutect2, varscan2
- RUNX1 | c.-737C>G | 5'UTR (SNP) | VAF 17/41 reads (41%) | called by muse, mutect2, varscan2
- SH3BGRL2 | c.*733A>G | 3'UTR (SNP) | VAF 30/74 reads (41%) | called by muse, mutect2, varscan2
- SLC9A4 | c.-297C>T | 5'UTR (SNP) | VAF 14/48 reads (29%) | catalogued as rs543378900; called by muse, mutect2, varscan2
- SYAP1 | c.*3297T>C | 3'UTR (SNP) | VAF 15/15 reads (100%) | called by muse, mutect2, varscan2
- SYT4 | c.*548G>A | 3'UTR (SNP) | VAF 53/106 reads (50%) | called by muse, mutect2, varscan2
- TASOR2 | c.7174+90T>C | Intron (SNP) | VAF 30/68 reads (44%) | called by muse, mutect2, varscan2
- TMCO5A | c.627+1004dup | Intron (INS) | VAF 17/43 reads (40%) | called by mutect2, pindel, varscan2
- TMEM182 | c.*391A>C | 3'UTR (SNP) | VAF 51/101 reads (50%) | called by muse, mutect2, varscan2
- TMEM65 | c.*1580T>G | 3'UTR (SNP) | VAF 40/84 reads (48%) | called by muse, mutect2, varscan2
- TOR1AIP2 | c.*5498A>C | 3'UTR (SNP) | VAF 34/110 reads (31%) | called by muse, mutect2, varscan2
- TPM2 | chr9:35682480 G>A | 3'Flank (SNP) | VAF 103/192 reads (54%) | called by muse, mutect2, varscan2
- WDR72 | c.*447C>A | 3'UTR (SNP) | VAF 5/94 reads (5%) | called by muse, mutect2
- WDR97 | c.*527C>T | 3'UTR (SNP) | VAF 60/132 reads (45%) | called by muse, mutect2, varscan2
- XPNPEP1 | c.247-20T>G | Intron (SNP) | VAF 27/60 reads (45%) | called by muse, mutect2, varscan2
- ZBBX | c.2138-5998C>T | Intron (SNP) | VAF 50/94 reads (53%) | called by muse, mutect2, varscan2
- ZIC4 | c.-15-1184A>C | Intron (SNP) | VAF 68/111 reads (61%) | called by muse, mutect2, varscan2
- ZMYM6 | c.428+890A>T | Intron (SNP) | VAF 18/20 reads (90%) | called by muse, mutect2, varscan2
